CCDI case PBCECZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/227eecac-3bc0-41c0-81d4-5de8cf335e71

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 6.6 years (2,395 days).

Biospecimens (1 sample)
- Sample 0DPSNN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
